FM case AD1592 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Adenomas and Adenocarcinomas.
https://portal.gdc.cancer.gov/cases/99c35945-88af-4753-9844-efabae7ce584

Male, 70.0 years: Neuroendocrine carcinoma, NOS (ICD-O-3 8246/3). Tumor nuclei on the sequenced sample's slide: 40% (pathologist estimate recorded by GDC). Sample type: Tumor.
